Surgical pathology report (de-identified scan), TCGA case TCGA-61-2610, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2610-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

PREVIOUS REPORTS

A) NODULE, SMALL BOWEL MESENTERY:

- FAT NECROSIS, FIBROSIS AND REACTIVE CHANGES, NEGATIVE FOR TUMOR

B,C,CFS1&2) CYST, MID WALL PELVIS:

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY

D,DFS) PORTION DESCENDING COLON:

- METASTATIC POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING SEROSA AND MUSCULARIS OF LARGE BOWEL

- SURGICAL MARGINS OF RESECTION, NEGATIVE FOR TUMOR

- FOUR (4) MESENTERIC LYMPH NODES, NEGATIVE FOR TUMOR (0/4)

Resident/Fellow:

Pathologist:

** Report Electronically Signed Out **

ICD-0-3

adenocarcinoma, serous papillary 8460/6

Site: bowel, large, NOS C18.9

hw
2/17/15
h

Source: NCI Genomic Data Commons file df87e903-9e45-4d93-8b34-c49cab3870d5 (TCGA-61-2610.361A67F5-2116-457D-988A-5B1E5D1A689B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).